TCGA case TCGA-DX-A8BO — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1610d467-e83f-490f-a971-7b099f3b46f8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (2)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 67.1 years (24,513 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 15; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 9; Tumor width measurement: 6.
2. Recurrence of diagnosis 1 (Undifferentiated sarcoma), site: Lower limb, NOS. Age at diagnosis: 68.0 years (24,846 days); Days to diagnosis: 333 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.7; Tumor length measurement: 1.5; Tumor width measurement: 0.7.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.7; Tumor length measurement: 1.5; Tumor width measurement: 0.7.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 333 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lower limb, NOS; Days to recurrence: 333 days.
- Day 333 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of lower limb and hip; Days to recurrence: 333 days.
- Days to follow up: 801 days (2.2 years); Disease response: Tumor Free.
- Days to follow up: 1,088 days (3.0 years); Disease response: Tumor Free.
- Days to follow up: 1,240 days (3.4 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A8BO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 310 mg.
  Slide TCGA-DX-A8BO-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A8BO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A8BO-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Pleomorphic 'MFH' / Undifferentiated pleomorphic sarcoma; Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 9; Lesion pathologic width: 6; Lesion pathologic depth: 4.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Radiation treatment: Days from index date to radiation therapy started: 382; Days from index date to radiation therapy ended: 417; Radiation therapy type: External; Radiation total dose: 5000; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 25; Radiation therapy site: Local Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,240 days; disease-specific survival: no event (censored), 1,240 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 333 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A8BO-01A-11D-A416-01): tumor purity 0.63, ploidy 1.65, whole-genome doublings 0.
